Somatic mutation profile of cancer-model specimen HCM-CSHL-0245-C18-85A (3D Organoid; aliquot HCM-CSHL-0245-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0245-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: GB; Age at diagnosis: 72.9 years (26,617 days).
Specimen HCM-CSHL-0245-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8e92b2-aff3-4f04-aff7-0972f63bfce4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0245-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0245-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/311d3a32-1d93-43a6-870f-6568e8e7b01f

The open-access MAF lists 226 somatic variants for this specimen: 157 protein-altering or splice-affecting, 57 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 57, Nonsense Mutation 14, Intron 5, 5'Flank 3, Frame Shift Del 3, RNA 2, 5'UTR 2, Frame Shift Ins 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 106/215 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99031505; called by muse, mutect2, varscan2
- AARD | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 249/692 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs534177737; called by muse, mutect2, varscan2
- ADCY2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 208/341 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs1168542317, COSV57861690, COSV57864042; called by muse, mutect2, varscan2
- ADGRB2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 264/560 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as rs1398217020; called by muse, varscan2
- ADIPOR1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 116/281 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as rs1040065193, COSV61852058; called by muse, mutect2, varscan2
- ANKRD30B | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV100745841; called by muse, mutect2, varscan2
- ARMCX2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 288/557 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1259351624, COSV57529232; called by muse, mutect2, varscan2
- ATM | c.3208G>A p.V1070I | Missense Mutation (SNP) | VAF 252/252 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs587780620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10D | c.3670G>T p.D1224Y | Missense Mutation (SNP) | VAF 107/212 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56711130; called by muse, mutect2, varscan2
- ATP9B | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs774905035; called by muse, mutect2, varscan2
- BMP8A | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs1460803803; called by muse, mutect2, varscan2
- BPGM | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV61324733; called by muse, mutect2
- CA6 | c.409-1G>T p.X137_splice | Splice Site (SNP) | VAF 32/270 reads (12%) | catalogued as COSV66261902; called by muse, mutect2, varscan2
- CCDC158 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 238/473 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as rs1329795418, COSV101187423, COSV66355999; called by muse, mutect2, varscan2
- CCDC69 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 383/383 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs747546885; called by muse, mutect2, varscan2
- CHRNB4 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 188/443 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55718615; called by muse, mutect2, varscan2
- CLASP1 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 241/409 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs763851949, COSV55320925; called by muse, mutect2, varscan2
- CRB1 | c.4090G>T p.V1364F | Missense Mutation (SNP) | VAF 202/372 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1437858539; called by muse, mutect2, varscan2
- CST5 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs771464838, COSV59013838; called by muse, mutect2
- DDN | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 168/605 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.169); catalogued as COSV60294370; called by muse, mutect2, varscan2
- DNAH8 | c.13313A>G p.N4438S | Missense Mutation (SNP) | VAF 127/620 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.402); catalogued as rs766001409; called by muse, mutect2, varscan2
- ENO3 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 142/299 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs534374372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLAD1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 222/411 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs201824694; called by muse, mutect2, varscan2
- FLRT3 | c.302A>T p.N101I | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374161251; called by muse, mutect2, varscan2
- GPC2 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 282/855 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs1193193792; called by muse, mutect2, varscan2
- HHLA1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 298/300 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764177411; called by muse, mutect2, varscan2
- HIVEP3 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 239/469 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs150086203; called by muse, mutect2, varscan2
- IGFN1 | c.2752C>T p.R918W (on ENST00000295591 / NM_001367841.1; = p.R3375W on NM_001164586.2) | Missense Mutation (SNP) | VAF 68/456 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276928055; called by muse, varscan2
- IGSF21 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 123/408 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs1557669094; called by muse, mutect2, varscan2
- IL7R | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 124/244 reads (51%) | catalogued as CM056607, COSV57409143; called by muse, mutect2
- KRTAP19-1 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 250/489 reads (51%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.155); catalogued as COSV101185867; called by muse, mutect2, varscan2
- LIN28A | c.154G>C p.G52R | Missense Mutation (SNP) | VAF 336/695 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575437; called by muse, mutect2, varscan2
- LRP2 | c.4345G>A p.D1449N | Missense Mutation (SNP) | VAF 151/412 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.794); catalogued as rs772588594, COSV55547681; called by muse, mutect2, varscan2
- MAST1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52241239; called by muse, mutect2, varscan2
- MNAT1 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs1266485681; called by muse, mutect2, varscan2
- MUC16 | c.16228G>A p.A5410T | Missense Mutation (SNP) | VAF 156/552 reads (28%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.021); catalogued as COSV67444967; called by muse, mutect2, varscan2
- NCKAP1L | c.1723T>G p.F575V | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53203329; called by muse, mutect2
- NFATC1 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 171/320 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781365067, COSV53702141; called by muse, mutect2, varscan2
- NME8 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs368696812, COSV52248056; called by muse, mutect2, varscan2
- OR4A16 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as COSV59042872, COSV59045268; called by muse, mutect2, varscan2
- PKHD1L1 | c.8669T>C p.I2890T | Missense Mutation (SNP) | VAF 288/288 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1425471818; called by muse, mutect2, varscan2
- PPP1R3A | c.1885G>T p.D629Y | Missense Mutation (SNP) | VAF 116/259 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs533288037; called by muse, mutect2, varscan2
- RAPGEF2 | c.943A>T p.K315* | Nonsense Mutation (SNP) | VAF 123/277 reads (44%) | catalogued as COSV52427435; called by muse, mutect2, varscan2
- RASGRF2 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs747963579, COSV54131808; called by muse, mutect2, varscan2
- RHBDL3 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 201/469 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761559210, COSV52189142; called by muse, mutect2, varscan2
- SDK1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs376569849; called by muse, mutect2, varscan2
- SLC14A2 | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 198/395 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs748642786, COSV104369992; called by muse, mutect2, varscan2
- SMG1 | c.10651C>G p.Q3551E | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.351); catalogued as COSV101246142, COSV67169170; called by muse, mutect2
- SMOC1 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 167/386 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs752262272, COSV62761244; called by muse, mutect2, varscan2
- SOAT2 | c.858C>A p.Y286* | Nonsense Mutation (SNP) | VAF 103/404 reads (25%) | catalogued as rs1444641284; called by muse, mutect2, varscan2
- SORCS1 | c.2416G>C p.D806H | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as COSV99551305; called by muse, mutect2, varscan2
- SORD | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1292851678; called by muse, mutect2
- SOX9 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 42/850 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs61740803, COSV55423157, COSV55430562; called by muse, mutect2
- SSTR3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 363/675 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766144463; called by muse, mutect2, varscan2
- THRB | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 108/594 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs754933969, COSV62835755; called by muse, mutect2, varscan2
- TICAM1 | c.1424G>C p.S475T | Missense Mutation (SNP) | VAF 183/412 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99940989; called by muse, mutect2, varscan2
- TLN2 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 167/325 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as COSV60891559; called by muse, mutect2, varscan2
- TMEM63C | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 249/499 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs866211915, COSV53601252; called by muse, mutect2, varscan2
- TTC39C | c.968G>A p.R323Q (on ENST00000317571 / NM_001135993.2; = p.R262Q on NM_153211.4) | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144967797, COSV58217556; called by muse, mutect2, varscan2
- VNN1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763783408, COSV63389358; called by muse, mutect2, varscan2
- ZBBX | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 203/406 reads (50%) | catalogued as rs770966283; called by muse, mutect2, varscan2
- ZC3H10 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 57/512 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs1340281307; called by muse, mutect2, varscan2
- ZFP28 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373914867, COSV56736279; called by muse, mutect2, varscan2
- ZNF536 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 278/483 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.415); catalogued as rs774965623, COSV62833030; called by muse, mutect2, varscan2
- ZNF717 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 138/486 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV68858615; called by muse, varscan2
- ABCA13 | c.12803C>T p.T4268I | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ABCA9 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- AC069544.2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 202/391 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ADGRG4 | c.1517C>G p.S506* | Nonsense Mutation (SNP) | VAF 183/364 reads (50%) | called by muse, mutect2, varscan2
- ADIPOQ | c.456C>A p.C152* | Nonsense Mutation (SNP) | VAF 42/824 reads (5%) | called by muse, mutect2
- AHNAK2 | c.5779G>A p.D1927N | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ALOX15B | c.1183T>A p.C395S | Missense Mutation (SNP) | VAF 201/385 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- APOBEC3C | c.65A>T p.K22I | Missense Mutation (SNP) | VAF 146/288 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ARAP1 | c.2119G>T p.A707S (on ENST00000393609 / NM_001040118.2; = p.A462S on NM_015242.4) | Missense Mutation (SNP) | VAF 91/588 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ASCC2 | c.1379dup p.A462Cfs*23 | Frame Shift Ins (INS) | VAF 158/441 reads (36%) | called by mutect2, pindel, varscan2
- BRD4 | c.848A>T p.K283M | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- C19orf81 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CCDC18 | c.3835G>A p.D1279N (on ENST00000343253 / NM_001306076.1; = p.D1280N on NM_206886.4) | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CFAP46 | c.4282T>A p.S1428T | Missense Mutation (SNP) | VAF 96/450 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLCC1 | c.780G>C p.W260C (on ENST00000356970 / NM_001377464.1; = p.W210C on NM_015127.5) | Missense Mutation (SNP) | VAF 145/307 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC14A | c.74C>A p.T25N | Missense Mutation (SNP) | VAF 459/818 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- CMPK2 | c.1223A>C p.Q408P | Missense Mutation (SNP) | VAF 118/217 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- COX5A | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- CPN1 | c.1100A>T p.D367V | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSPG4 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 281/593 reads (47%) | called by muse, mutect2, varscan2
- CTNNA1 | c.2529C>A p.Y843* | Nonsense Mutation (SNP) | VAF 326/326 reads (100%) | called by muse, mutect2, varscan2
- CYP2C19 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 79/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1A | c.977A>T p.E326V | Missense Mutation (SNP) | VAF 100/227 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DSP | c.7617dup p.D2540* | Frame Shift Ins (INS) | VAF 270/571 reads (47%) | called by mutect2, pindel, varscan2
- EFCC1 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 40/1220 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EXOC3L1 | c.2185C>A p.P729T | Missense Mutation (SNP) | VAF 307/689 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FANCM | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- FASTKD5 | c.2039A>T p.E680V | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FER1L5 | c.3226C>T p.Q1076* (on ENST00000623019; = p.Q1049* on NM_001293083.2) | Nonsense Mutation (SNP) | VAF 70/831 reads (8%) | called by muse, mutect2
- FOXN2 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 202/348 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GALNT13 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 161/301 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- GDPGP1 | c.955del p.S319Afs*4 | Frame Shift Del (DEL) | VAF 210/473 reads (44%) | called by mutect2, pindel, varscan2
- GINS2 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- GULP1 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- HYDIN | c.10384C>T p.R3462* | Nonsense Mutation (SNP) | VAF 100/224 reads (45%) | called by muse, mutect2, varscan2
- IMPG1 | c.1262C>G p.T421R | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ITPR3 | c.7054G>A p.E2352K | Missense Mutation (SNP) | VAF 271/443 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAK2 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- KLHL34 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 317/666 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KMT2D | c.729C>G p.F243L | Missense Mutation (SNP) | VAF 266/526 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- KRT24 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 170/420 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- KRT40 | c.307T>A p.Y103N | Missense Mutation (SNP) | VAF 157/606 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP1-3 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 102/846 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LENG1 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 161/533 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MAFB | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 90/660 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB18 | c.300G>C p.E100D | Missense Mutation (SNP) | VAF 198/417 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAP2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 214/368 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MAP4 | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 123/486 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MAPK8IP2 | c.1691C>A p.S564* | Nonsense Mutation (SNP) | VAF 92/657 reads (14%) | called by muse, mutect2, varscan2
- MEI4 | c.385C>G p.H129D | Missense Mutation (SNP) | VAF 261/435 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MROH2A | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 116/326 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRPL55 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 58/473 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MUC16 | c.25969C>A p.H8657N | Missense Mutation (SNP) | VAF 189/412 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MXRA5 | c.7283G>A p.R2428K | Missense Mutation (SNP) | VAF 331/620 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.682); called by muse, mutect2
- NBAS | c.7060C>A p.H2354N | Missense Mutation (SNP) | VAF 21/721 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- NISCH | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 194/553 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- NKG7 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLRP2 | c.2313T>A p.F771L | Missense Mutation (SNP) | VAF 248/498 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOL9 | c.1717G>T p.V573L | Missense Mutation (SNP) | VAF 16/528 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2
- NOLC1 | c.385A>C p.S129R | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR2F1 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 254/519 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAK3 | c.1671C>A p.S557R (on ENST00000262836 / NM_001324328.2; = p.S542R on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/282 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by mutect2, varscan2
- PAPPA | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 151/680 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDCD6IP | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.1531A>C p.S511R | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDPN | c.430T>G p.F144V (on ENST00000621990; = p.F220V on NM_006474.4) | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PICALM | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 182/182 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.182); called by mutect2, varscan2
- PLEC | c.1048C>T p.Q350* (on ENST00000322810 / NM_201380.4; = p.Q240* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 46/351 reads (13%) | called by muse, mutect2, varscan2
- PPP1R3A | c.2795T>A p.I932N | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- PTPRU | c.1120C>A p.L374I | Missense Mutation (SNP) | VAF 209/426 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RTL3 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); called by muse, mutect2
- SHANK1 | c.6185C>A p.S2062Y | Missense Mutation (SNP) | VAF 291/603 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- SLC1A4 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 246/435 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- SMG1 | c.3210A>T p.E1070D | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); called by muse, mutect2
- SMS | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SORCS1 | c.2417A>T p.D806V | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- STOX1 | c.172del p.S58Rfs*54 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel*
- TAF3 | c.2077A>T p.K693* | Nonsense Mutation (SNP) | VAF 24/228 reads (11%) | called by mutect2, varscan2
- TBCD | c.1338G>T p.K446N | Missense Mutation (SNP) | VAF 166/387 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TMEM132D | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 51/642 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2
- TOPAZ1 | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 209/317 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRAFD1 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUT7 | c.2837T>G p.F946C | Missense Mutation (SNP) | VAF 203/203 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- VENTX | c.534T>A p.N178K | Missense Mutation (SNP) | VAF 206/688 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- WNK2 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 302/354 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZDHHC23 | c.1088C>G p.A363G | Missense Mutation (SNP) | VAF 173/643 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFP36L1 | c.436del p.S146Afs*2 | Frame Shift Del (DEL) | VAF 255/594 reads (43%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.550_588del p.R184_L196del | In Frame Del (DEL) | VAF 133/559 reads (24%) | called by mutect2, varscan2
- ZNF600 | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 103/244 reads (42%) | called by mutect2, varscan2
- ZNF74 | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZNRF3 | c.689C>T p.S230F (on ENST00000544604 / NM_001206998.2; = p.S130F on NM_032173.3) | Missense Mutation (SNP) | VAF 212/392 reads (54%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ZRANB3 | c.1906T>A p.S636T | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ABCA13 | c.12441A>T p.S4147= | Silent (SNP) | VAF 93/261 reads (36%) | catalogued as COSV101446923; called by muse, mutect2, varscan2
- ADARB1 | c.1065C>A p.V355= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- ADORA1 | c.616C>T p.L206= | Silent (SNP) | VAF 229/461 reads (50%) | called by muse, mutect2, varscan2
- ALAS1 | c.717C>T p.L239= | Silent (SNP) | VAF 166/656 reads (25%) | catalogued as COSV59628619; called by muse, mutect2, varscan2
- ANKRD28 | c.390G>A p.L130= | Silent (SNP) | VAF 71/663 reads (11%) | called by muse, mutect2, varscan2
- ASB14 | c.954T>C p.V318= | Silent (SNP) | VAF 175/497 reads (35%) | called by muse, mutect2, varscan2
- BCOR | c.2721C>T p.S907= | Silent (SNP) | VAF 233/531 reads (44%) | catalogued as rs1349371387; called by muse, mutect2, varscan2
- CARD11 | c.627A>G p.A209= | Silent (SNP) | VAF 267/445 reads (60%) | called by muse, mutect2, varscan2
- CD200R1 | c.126C>T p.L42= (on ENST00000471858 / NM_170780.3; = p.L65= on NM_138806.4) | Silent (SNP) | VAF 108/431 reads (25%) | catalogued as rs897611284; called by muse, mutect2, varscan2
- CECR2 | c.1071G>A p.R357= (on ENST00000342247 / NM_001290047.2; = p.R194= on NM_001290046.1) | Silent (SNP) | VAF 21/475 reads (4%) | called by muse, mutect2
- CHRNA4 | c.345C>T p.S115= | Silent (SNP) | VAF 307/481 reads (64%) | catalogued as rs201033859, COSV100937285; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHST10 | c.622C>A p.R208= | Silent (SNP) | VAF 199/367 reads (54%) | called by muse, mutect2, varscan2
- CSMD2 | c.8436C>T p.R2812= | Silent (SNP) | VAF 48/397 reads (12%) | catalogued as rs148880986, COSV53951347; called by muse, mutect2, varscan2
- CUBN | c.10212C>A p.G3404= | Silent (SNP) | VAF 162/320 reads (51%) | called by muse, mutect2, varscan2
- DACT2 | c.2145G>T p.L715= | Silent (SNP) | VAF 36/1164 reads (3%) | called by muse, mutect2
- DHX16 | c.2124G>T p.S708= | Silent (SNP) | VAF 206/520 reads (40%) | catalogued as rs906936810; called by muse, mutect2, varscan2
- DHX58 | c.558G>A p.L186= | Silent (SNP) | VAF 237/435 reads (54%) | called by muse, mutect2, varscan2
- EPB41L2 | c.2790T>C p.S930= | Silent (SNP) | VAF 181/503 reads (36%) | called by muse, mutect2, varscan2
- FOXI2 | c.618C>T p.R206= | Silent (SNP) | VAF 145/560 reads (26%) | called by muse, mutect2, varscan2
- G6PC3 | c.879G>A p.L293= | Silent (SNP) | VAF 302/561 reads (54%) | catalogued as rs780718603; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJA3 | c.627G>A p.A209= | Silent (SNP) | VAF 219/681 reads (32%) | catalogued as rs1278306213; called by muse, mutect2, varscan2
- GLI3 | c.147T>G p.T49= | Silent (SNP) | VAF 58/318 reads (18%) | called by muse, mutect2, varscan2
- GLIS2 | c.1245G>A p.P415= | Silent (SNP) | VAF 440/900 reads (49%) | catalogued as rs755435780; ClinVar: likely benign; called by muse, mutect2
- GOLGA8A | c.1599C>T p.H533= (on ENST00000432566; = p.H505= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 101/389 reads (26%) | catalogued as rs1480564491; called by muse, mutect2, varscan2
- IGF2 | c.462G>A p.P154= (on ENST00000434045 / NM_001127598.3; = p.P98= on NM_000612.6) | Silent (SNP) | VAF 387/387 reads (100%) | catalogued as COSV56097151; called by muse, mutect2, varscan2
- IPO4 | c.2250A>G p.R750= | Silent (SNP) | VAF 53/426 reads (12%) | called by muse, mutect2, varscan2
- KCTD8 | c.759C>T p.N253= | Silent (SNP) | VAF 266/538 reads (49%) | catalogued as COSV63592481; called by muse, mutect2, varscan2
- LDOC1 | c.408C>T p.D136= | Silent (SNP) | VAF 192/404 reads (48%) | catalogued as COSV100983116; called by muse, mutect2, varscan2
- LOXHD1 | c.1641C>T p.R547= | Silent (SNP) | VAF 123/275 reads (45%) | called by muse, mutect2, varscan2
- LRP1B | c.13755G>A p.L4585= | Silent (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- MDN1 | c.3642G>C p.R1214= | Silent (SNP) | VAF 207/325 reads (64%) | called by muse, mutect2, varscan2
- MDN1 | c.1416C>T p.H472= | Silent (SNP) | VAF 330/449 reads (73%) | called by muse, mutect2, varscan2
- MTO1 | c.123C>G p.V41= | Silent (SNP) | VAF 344/866 reads (40%) | catalogued as rs1351045114; called by muse, mutect2, varscan2
- MYO1E | c.1335C>T p.I445= | Silent (SNP) | VAF 104/237 reads (44%) | catalogued as rs200815044, COSV55690417; called by muse, mutect2, varscan2
- OS9 | c.1911C>T p.R637= | Silent (SNP) | VAF 170/436 reads (39%) | catalogued as rs754652717; called by muse, mutect2, varscan2
- PCDH9 | c.1239G>A p.A413= | Silent (SNP) | VAF 129/391 reads (33%) | catalogued as rs372255783; called by muse, varscan2
- PHF2 | c.2790C>T p.I930= | Silent (SNP) | VAF 314/384 reads (82%) | catalogued as rs148663364; called by muse, mutect2, varscan2
- POM121L12 | c.585G>A p.P195= | Silent (SNP) | VAF 236/771 reads (31%) | catalogued as rs781667306, COSV68692555; called by muse, mutect2, varscan2
- PTCHD1 | c.6G>T p.L2= | Silent (SNP) | VAF 42/303 reads (14%) | called by muse, mutect2, varscan2
- RASGRF1 | c.1650C>T p.I550= | Silent (SNP) | VAF 167/334 reads (50%) | catalogued as rs756158411, COSV69176724; called by muse, mutect2, varscan2
- RHOBTB1 | c.624G>A p.L208= | Silent (SNP) | VAF 128/279 reads (46%) | catalogued as rs772792443; called by muse, mutect2, varscan2
- RNF224 | c.258G>A p.L86= | Silent (SNP) | VAF 100/772 reads (13%) | called by muse, mutect2, varscan2
- SCN1B | c.570G>A p.E190= | Silent (SNP) | VAF 167/345 reads (48%) | called by muse, mutect2, varscan2
- SCN5A | c.987C>T p.S329= | Silent (SNP) | VAF 145/410 reads (35%) | called by muse, mutect2, varscan2
- SI | c.3297C>T p.F1099= | Silent (SNP) | VAF 190/454 reads (42%) | called by muse, mutect2, varscan2
- SLC35F1 | c.888C>A p.L296= | Silent (SNP) | VAF 164/388 reads (42%) | called by muse, mutect2, varscan2
- SUSD4 | c.381C>T p.I127= | Silent (SNP) | VAF 134/287 reads (47%) | catalogued as rs776519802, COSV59553299; called by muse, mutect2, varscan2
- TPO | c.1287C>T p.S429= | Silent (SNP) | VAF 375/695 reads (54%) | called by muse, mutect2, varscan2
- TRAV26-1 | c.282C>T p.H94= | Silent (SNP) | VAF 114/282 reads (40%) | catalogued as rs757745985; called by muse, mutect2, varscan2
- TRPC5 | c.480G>A p.L160= | Silent (SNP) | VAF 22/610 reads (4%) | catalogued as rs1371045356; called by muse, mutect2
- TTLL7 | c.2625C>A p.R875= | Silent (SNP) | VAF 48/209 reads (23%) | called by muse, mutect2, varscan2
- TXNDC11 | c.99C>T p.L33= | Silent (SNP) | VAF 424/866 reads (49%) | catalogued as COSV51601050; called by muse, mutect2
- UNC119 | c.210G>A p.R70= | Silent (SNP) | VAF 102/476 reads (21%) | called by muse, varscan2
- USP35 | c.1665C>T p.P555= | Silent (SNP) | VAF 359/359 reads (100%) | catalogued as rs376772946; called by muse, mutect2, varscan2
- WDFY4 | c.2889T>C p.A963= | Silent (SNP) | VAF 38/350 reads (11%) | called by muse, mutect2, varscan2
- ZIC1 | c.285C>T p.N95= | Silent (SNP) | VAF 289/1122 reads (26%) | called by muse, mutect2, varscan2
- ZNF607 | c.1212C>T p.L404= | Silent (SNP) | VAF 50/353 reads (14%) | catalogued as rs1029859805; called by muse, mutect2, varscan2
- C3orf38 | c.-1G>A | 5'UTR (SNP) | VAF 80/331 reads (24%) | called by muse, mutect2, varscan2
- CBARP | c.1214+118C>A | Intron (SNP) | VAF 400/758 reads (53%) | called by muse, mutect2, varscan2
- DIRC1 | n.495T>A | RNA (SNP) | VAF 39/321 reads (12%) | called by muse, mutect2, varscan2
- G6PD | c.-4C>T | 5'UTR (SNP) | VAF 161/355 reads (45%) | catalogued as rs781792803; called by muse, mutect2, varscan2
- LINC01018 | n.1185C>A | RNA (SNP) | VAF 309/575 reads (54%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31640163 C>A | 5'Flank (SNP) | VAF 280/452 reads (62%) | called by mutect2, varscan2
- RNU6-104P | chr8:43302021 T>A | 5'Flank (SNP) | VAF 15/318 reads (5%) | called by muse, mutect2
- RNU6-104P | chr8:43302022 C>A | 5'Flank (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- ROBO2 | c.3761-2230C>A | Intron (SNP) | VAF 82/298 reads (28%) | called by muse, mutect2, varscan2
- RXFP1 | c.465-908A>G | Intron (SNP) | VAF 134/288 reads (47%) | catalogued as rs1015594014, COSV57048211; called by muse, mutect2, varscan2
- STOX1 | c.310+198_310+248delinsA | Intron (DEL) | VAF 33/273 reads (12%) | called by pindel, varscan2*
- TTN | c.34265-3224C>A | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs1449282705; called by mutect2, varscan2
